Somatic mutation profile of tumor specimen TCGA-70-6723-01A (aliquot TCGA-70-6723-01A-11D-1817-08) from TCGA case TCGA-70-6723, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.8 years (24,035 days).
Specimen TCGA-70-6723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39b35eb0-bad0-43a0-9e62-d40a36b9e041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-70-6723-10A (Blood Derived Normal), aliquot TCGA-70-6723-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d1624ca-c568-4f9e-95f3-57661d2faf89

The open-access MAF lists 119 somatic variants for this specimen: 87 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 26, Frame Shift Del 4, Intron 3, Splice Site 3, Nonsense Mutation 3, In Frame Del 1, 5'Flank 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 91/101 reads (90%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- ACSL6 | c.926T>G p.F309C (on ENST00000379240; = p.F334C on NM_001009185.3) | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV99734468; called by muse, mutect2, varscan2
- AKAP3 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 80/131 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV57420355; called by muse, mutect2, varscan2
- APLP1 | c.1652T>A p.V551E (on ENST00000221891 / NM_001024807.3; = p.V550E on NM_005166.4) | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV55706792; called by muse, mutect2, varscan2
- ATXN7L3 | c.968G>T p.G323V (on ENST00000389384 / NM_001382309.1; = p.G330V on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/139 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV60229865; called by muse, mutect2, varscan2
- BUB1 | c.2471A>C p.K824T | Missense Mutation (SNP) | VAF 69/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57067173; called by muse, mutect2, varscan2
- C20orf27 | c.478G>T p.E160* (on ENST00000379772 / NM_001258429.2; = p.E185* on NM_001039140.3) | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV53925329; called by muse, mutect2, varscan2
- CCDC88B | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs769104707, COSV57264926; called by muse, mutect2, varscan2
- CD226 | c.929C>G p.T310S | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV54615975; called by muse, mutect2, varscan2
- CDHR3 | c.2347G>T p.D783Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58421489; called by muse, mutect2
- CEP162 | c.2932G>A p.G978S | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV57624435; called by muse, mutect2, varscan2
- CLIP2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99792113; called by mutect2, varscan2
- CRISP3 | c.797A>T p.K266M (on ENST00000371159 / NM_001368123.1; = p.K248M on NM_006061.4) | Missense Mutation (SNP) | VAF 204/213 reads (96%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV53823205; called by muse, mutect2, varscan2
- CYFIP2 | c.1592G>C p.C531S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.784); catalogued as COSV59050111; called by muse, mutect2, varscan2
- DMD | c.1305G>C p.R435S | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55857259; called by muse, mutect2, varscan2
- DNAH9 | c.8342T>C p.L2781P | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52375649; called by muse, mutect2, varscan2
- EMILIN2 | c.2048C>A p.S683* | Nonsense Mutation (SNP) | VAF 44/213 reads (21%) | catalogued as rs544310868, COSV54424718, COSV54427375; called by muse, mutect2, varscan2
- EPB41L3 | c.2974-2A>C p.X992_splice | Splice Site (SNP) | VAF 57/276 reads (21%) | catalogued as COSV59467352; called by muse, mutect2, varscan2
- ERV3-1 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT tolerated (0.89); catalogued as COSV99276003; called by muse, varscan2
- FOXK1 | c.1450C>G p.P484A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV61068567; called by muse, mutect2, varscan2
- FRMPD1 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 80/94 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV66702979; called by muse, mutect2, varscan2
- FSD1 | c.357A>T p.Q119H | Missense Mutation (SNP) | VAF 161/197 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV55698760; called by muse, mutect2, varscan2
- FSHR | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs867447724, COSV58619761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYN | c.1324A>G p.R442G | Missense Mutation (SNP) | VAF 108/125 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV57620783; called by muse, mutect2, varscan2
- GPT2 | c.902T>A p.V301E | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60840210; called by muse, mutect2, varscan2
- HBB | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 91/106 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as CM930373, COSV58943146; called by muse, mutect2, varscan2
- HECTD4 | c.4156C>T p.Q1386* | Nonsense Mutation (SNP) | VAF 25/36 reads (69%) | catalogued as COSV61181483; called by muse, mutect2, varscan2
- HHIPL2 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as COSV58567664; called by muse, mutect2
- HLF | c.773C>G p.S258W | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56829665, COSV56832236; called by muse, mutect2, varscan2
- HS3ST2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54462986; called by muse, mutect2, varscan2
- HSD17B1 | c.856G>C p.G286R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV56798580; called by muse, mutect2
- IQUB | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV61242631; called by muse, mutect2, varscan2
- ITGB4 | c.2525A>T p.Q842L | Missense Mutation (SNP) | VAF 67/104 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV52332342; called by muse, mutect2, varscan2
- ITIH5 | c.385A>C p.T129P | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV56901242; called by muse, mutect2, varscan2
- KIAA1841 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 171/376 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV54373613, COSV54378717; called by muse, mutect2, varscan2
- KNL1 | c.5066G>A p.C1689Y (on ENST00000346991 / NM_170589.5; = p.C1663Y on NM_144508.5) | Missense Mutation (SNP) | VAF 78/160 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs772043978, COSV61160184; called by muse, mutect2, varscan2
- LCN2 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV52981886; called by muse, mutect2, varscan2
- LRRC58 | c.661A>T p.N221Y | Missense Mutation (SNP) | VAF 64/80 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55231142; called by muse, mutect2, varscan2
- LRRC71 | c.913C>G p.R305G | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV61656786; called by muse, mutect2
- LTBP1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV63197637; called by muse, mutect2, varscan2
- MAP1A | c.5089T>A p.W1697R | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); catalogued as COSV55805560; called by muse, mutect2, varscan2
- MCF2L | c.2455G>T p.G819C (on ENST00000375608; = p.G787C on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56181353; called by muse, mutect2, varscan2
- MECOM | c.835G>T p.A279S (on ENST00000468789 / NM_001105078.4; = p.A467S on NM_004991.4) | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.09); catalogued as rs755177704, COSV52974028; called by muse, mutect2, varscan2
- MEMO1 | c.143del p.H49Mfs*113 | Frame Shift Del (DEL) | VAF 81/230 reads (35%) | catalogued as COSV54455853; called by mutect2, pindel, varscan2
- MROH2B | c.2843A>G p.Q948R | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV68189262; called by muse, mutect2, varscan2
- MYO7A | c.445A>G p.S149G | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV68686960; called by muse, mutect2, varscan2
- NMNAT2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as COSV54271449; called by muse, mutect2, varscan2
- NOLC1 | c.414G>C p.E138D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV64181093; called by muse, mutect2, varscan2
- NOX5 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52995710; called by muse, mutect2, varscan2
- OR10Q1 | c.778T>A p.C260S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as COSV57471928; called by muse, mutect2, varscan2
- OR1S1 | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 79/131 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58708525; called by muse, mutect2, varscan2
- OR4K14 | c.218G>T p.W73L | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV59294161; called by muse, mutect2, varscan2
- OR8B2 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 137/189 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100899472, COSV66664888; called by muse, mutect2, varscan2
- OXR1 | c.1568A>G p.Q523R (on ENST00000442977 / NM_001198532.1; = p.Q522R on NM_018002.3) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.218); catalogued as COSV56335970; called by muse, mutect2, varscan2
- PAPPA | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 103/147 reads (70%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV60291334; called by muse, mutect2, varscan2
- PCSK1 | c.737C>G p.T246R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60735394, COSV60737452; called by muse, mutect2, varscan2
- PDCD10 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV67102521; called by muse, mutect2
- PDE1C | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.103); catalogued as rs267601486, COSV58516968, COSV58527985; called by muse, mutect2, varscan2
- PDE4B | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100304616; called by mutect2, varscan2
- PIGF | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.239); catalogued as COSV53232244; called by muse, mutect2, varscan2
- PPIL3 | c.226A>T p.S76C (on ENST00000392283 / NM_130906.3; = p.S80C on NM_032472.4) | Missense Mutation (SNP) | VAF 165/211 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV53770332; called by muse, mutect2, varscan2
- PRDX6 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61166274; called by muse, mutect2
- PRSS1 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1338646513, COSV61192223; called by muse, mutect2, varscan2
- PXDN | c.2211C>A p.F737L | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV53245846, COSV99413489; called by muse, mutect2
- RASGRF2 | c.3621+1G>C p.X1207_splice | Splice Site (SNP) | VAF 12/30 reads (40%) | catalogued as COSV54139128; called by muse, varscan2
- RPS20 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV50537105; called by muse, mutect2, varscan2
- RRM2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs753054700, COSV58817926; called by muse, mutect2, varscan2
- SAXO1 | c.197T>C p.M66T | Missense Mutation (SNP) | VAF 132/152 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV65871915; called by muse, mutect2, varscan2
- SI | c.3624A>T p.Q1208H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52299993; called by muse, mutect2, varscan2
- SLIT3 | c.4133A>T p.H1378L | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60632225; called by muse, mutect2, varscan2
- SPNS1 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV57956684; called by muse, mutect2, varscan2
- TBC1D31 | c.1462T>A p.S488T | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV54870860; called by muse, mutect2, varscan2
- TCOF1 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV104405846, COSV60354032; called by muse, mutect2, varscan2
- TNIK | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV52695407; called by muse, mutect2
- TRPC5 | c.34T>A p.S12T | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV53302398; called by muse, mutect2, varscan2
- UBXN1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV53658699; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3945G>C p.M1315I | Missense Mutation (SNP) | VAF 177/186 reads (95%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV51960302; called by muse, mutect2, varscan2
- UNC5C | c.2431C>T p.L811F | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71662100; called by muse, mutect2, varscan2
- XIRP2 | c.4200T>A p.D1400E (on ENST00000628543; = p.D1575E on NM_152381.6) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV54732740; called by muse, mutect2, varscan2
- YBX3 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 95/168 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54386947; called by muse, mutect2, varscan2
- ZGRF1 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 83/103 reads (81%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV52203194; called by muse, mutect2, varscan2
- ZNF804A | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 112/264 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV56470428; called by muse, mutect2, varscan2
- CRIM1 | c.1441_1446del p.D481_C482del | In Frame Del (DEL) | VAF 50/138 reads (36%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NT5M | c.244_257del p.G82Rfs*18 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- NUTM1 | c.922del p.L308Cfs*7 | Frame Shift Del (DEL) | VAF 58/133 reads (44%) | called by mutect2, pindel, varscan2
- OR2B11 | c.328del p.W110Gfs*57 | Frame Shift Del (DEL) | VAF 56/112 reads (50%) | called by mutect2, pindel, varscan2
- ALCAM | c.453A>G p.L151= | Silent (SNP) | VAF 117/144 reads (81%) | catalogued as rs371767685; called by muse, mutect2, varscan2
- APEX2 | c.1068G>C p.T356= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as rs774201190, COSV58192571, COSV58193180; called by muse, mutect2, varscan2
- ASPM | c.4704A>T p.S1568= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV54138348; called by muse, mutect2, varscan2
- CRACDL | c.2025G>T p.P675= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV67408190, COSV67410071; called by muse, mutect2, varscan2
- DCTN1 | c.177C>T p.G59= | Silent (SNP) | VAF 82/164 reads (50%) | catalogued as rs72466484, COSV62620993, COSV62621457; called by muse, mutect2, varscan2
- FAM71B | c.384G>T p.V128= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV57230899; called by muse, mutect2, varscan2
- FOXN2 | c.1293A>G p.K431= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV61319814; called by muse, mutect2, varscan2
- GAD2 | c.1680C>A p.V560= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as rs1340371462, COSV52167803; called by muse, varscan2
- GUCY1A1 | c.1953C>T p.P651= | Silent (SNP) | VAF 79/92 reads (86%) | catalogued as rs150400396; called by muse, mutect2, varscan2
- HERC2 | c.12072G>A p.S4024= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs1383413452, COSV55349222; called by muse, mutect2, varscan2
- MED14 | c.1374A>G p.L458= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as COSV61358490; called by muse, mutect2, varscan2
- MFSD6L | c.1257G>T p.P419= | Silent (SNP) | VAF 147/315 reads (47%) | catalogued as rs765375603, COSV61003606, COSV61005836; called by muse, mutect2, varscan2
- MUC5B | c.4782G>A p.R1594= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as COSV71595295; called by muse, mutect2, varscan2
- NOX1 | c.792G>A p.G264= | Silent (SNP) | VAF 106/113 reads (94%) | catalogued as COSV54196501; called by muse, mutect2, varscan2
- NPTXR | c.687C>T p.T229= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV60728941, COSV60729561; called by muse, mutect2
- PCDHA8 | c.408A>G p.K136= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as COSV100971119, COSV65340349; called by muse, varscan2
- PCDHGB6 | c.1114C>A p.R372= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV54027199; called by muse, mutect2, varscan2
- PDE7B | c.189T>C p.I63= | Silent (SNP) | VAF 89/101 reads (88%) | catalogued as COSV57508434; called by muse, mutect2, varscan2
- PGM2L1 | c.1668A>G p.T556= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV53349414; called by muse, mutect2, varscan2
- PHF20L1 | c.1887A>G p.L629= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as rs1403255377, COSV55197888; called by muse, mutect2, varscan2
- PITPNM3 | c.147C>T p.I49= | Silent (SNP) | VAF 221/238 reads (93%) | catalogued as COSV52599852; called by muse, mutect2, varscan2
- PRDM2 | c.1221A>C p.R407= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV52442845; called by muse, mutect2, varscan2
- RPRD2 | c.1026A>T p.G342= | Silent (SNP) | VAF 116/381 reads (30%) | catalogued as COSV64823212; called by muse, mutect2, varscan2
- SPANXB1 | c.183C>T p.Y61= | Silent (SNP) | VAF 17/351 reads (5%) | called by muse, mutect2
- TRAV8-1 | c.111A>C p.S37= | Silent (SNP) | VAF 320/533 reads (60%) | called by muse, mutect2, varscan2
- UNC79 | c.2874C>T p.T958= (on ENST00000393151 / NM_001346218.2; = p.T781= on NM_020818.5) | Silent (SNP) | VAF 55/63 reads (87%) | catalogued as rs1230070411, COSV56409182; called by muse, varscan2
- AL353804.7 | chrX:73851574 C>T | 3'Flank (SNP) | VAF 36/75 reads (48%) | catalogued as rs756714415; called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1903C>A | Intron (SNP) | VAF 92/163 reads (56%) | catalogued as COSV99151296; called by muse, mutect2, varscan2
- HOXD4 | chr2:176150376 G>A | 5'Flank (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- MGAM | c.4618+3216G>A | Intron (SNP) | VAF 5/99 reads (5%) | catalogued as rs756917594, COSV101527705; called by muse, mutect2
- MIR551B | n.32G>A | RNA (SNP) | VAF 16/240 reads (7%) | catalogued as rs756838380; called by muse, mutect2
- TTN | c.34265-5080C>T | Intron (SNP) | VAF 91/450 reads (20%) | catalogued as rs555029471, COSV59903942; called by muse, mutect2, varscan2
